CCDI case PBBTPN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/55c0645a-ad8e-40e5-aa1b-e3265dded164

Demographics
Sex at birth: female; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of head, face, and neck; Age at diagnosis: 13.4 years (4,885 days).

Biospecimens (3 samples)
- Sample 0DGRG5: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DGRHL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DGRHS: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
